Somatic mutation profile of tumor specimen C3N-02275-03 (aliquot CPT0163740007) from CPTAC case C3N-02275, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 69.5 years (25,376 days).
Specimen C3N-02275-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c7e8b76-1957-4a28-a1d3-e5efbe5b10b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02275-31 (Blood Derived Normal), aliquot CPT0163780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/676c800a-1f2e-4fae-8f8d-a3ce58e125a2

The open-access MAF lists 917 somatic variants for this specimen: 582 protein-altering or splice-affecting, 200 silent, 135 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 490, Silent 200, Intron 69, Nonsense Mutation 53, 5'UTR 17, 3'UTR 16, RNA 14, Splice Region 14, Splice Site 13, 5'Flank 12, 3'Flank 7, Frame Shift Del 6.

Variants (750 of 917; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDAR | c.442+1G>A p.X148_splice | Splice Site (SNP) | VAF 96/310 reads (31%) | catalogued as rs368841777, CS101464; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAN1B1 | c.1942C>T p.Q648* | Nonsense Mutation (SNP) | VAF 117/488 reads (24%) | catalogued as rs1164484724, COSV65371847; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1627C>T p.Q543* | Nonsense Mutation (SNP) | VAF 31/196 reads (16%) | catalogued as rs894292181, CM020463, COSV62211373; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4021C>T p.Q1341* | Nonsense Mutation (SNP) | VAF 61/323 reads (19%) | catalogued as rs137854559, COSV62194083; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.248T>C p.F83S | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as rs1560137208, COSV55924440, COSV55950009; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 136/752 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.3691C>G p.R1231G | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766285158, CM067623, COSV55591407; called by muse, mutect2, varscan2
- ABCC1 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 56/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60691371; called by muse, mutect2, varscan2
- ABI3BP | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs1352652631; called by muse, mutect2, varscan2
- ACSL4 | c.571C>T p.H191Y (on ENST00000340800 / NM_022977.2; = p.H150Y on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV61614365; called by muse, mutect2, varscan2
- ADAM29 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as rs1173714434, COSV100821886, COSV100822111; called by muse, mutect2
- ADAMTS20 | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 52/301 reads (17%) | catalogued as COSV67130722, COSV67135166; called by muse, mutect2, varscan2
- ADCK5 | c.1226A>C p.D409A | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as rs782208902, COSV58233174; called by muse, mutect2, varscan2
- ADGRG4 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs779941213, COSV54951266; called by muse, mutect2, varscan2
- AJUBA | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 34/210 reads (16%) | catalogued as COSV99401112; called by muse, mutect2, varscan2
- AL357075.4 | c.1386G>C p.K462N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV99499518; called by muse, mutect2, varscan2
- ALOX5 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 99/575 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65551841; called by muse, mutect2, varscan2
- ANKRD30B | c.2828C>T p.S943L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100271359; called by mutect2, varscan2
- ANKUB1 | c.1160G>C p.S387T | Missense Mutation (SNP) | VAF 53/312 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs753103675; called by muse, mutect2, varscan2
- ANXA4 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs746085005; called by muse, mutect2
- ANXA9 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 71/340 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV64484554; called by muse, mutect2, varscan2
- ARID2 | c.4361C>G p.S1454* | Nonsense Mutation (SNP) | VAF 34/175 reads (19%) | catalogued as COSV57602195; called by muse, mutect2, varscan2
- ARID2 | c.4774-1G>C p.X1592_splice | Splice Site (SNP) | VAF 23/86 reads (27%) | catalogued as COSV57605676; called by muse, mutect2, varscan2
- ASPM | c.6155C>T p.S2052F | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99659318; called by muse, mutect2, varscan2
- ASRGL1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs548516214; called by muse, mutect2, varscan2
- ATP1B1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs267598155, COSV100891056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 115/429 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.719); catalogued as rs782614609, COSV54866290; called by muse, mutect2, varscan2
- ATRIP | c.1761C>G p.F587L | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs375679861; called by muse, mutect2, varscan2
- ATRX | c.4754C>T p.S1585F | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64872748; called by muse, mutect2, varscan2
- B3GALT6 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1267101770; called by muse, mutect2, varscan2
- BNC2 | c.1172C>A p.T391N | Missense Mutation (SNP) | VAF 100/360 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101034489; called by muse, mutect2, varscan2
- BNIP5 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 52/312 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as COSV71325407; called by muse, mutect2, varscan2
- BPTF | c.4558G>C p.E1520Q | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV58838823; called by muse, mutect2, varscan2
- BRD8 | c.2096G>A p.C699Y (on ENST00000254900 / NM_139199.2; = p.C772Y on NM_006696.4) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1174736614; called by muse, mutect2, varscan2
- C8orf34 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1420845928; called by muse, mutect2
- CASP8AP2 | c.4544G>A p.R1515Q | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776315628; called by muse, mutect2, varscan2
- CATSPER1 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 80/324 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs200806107; called by muse, mutect2, varscan2
- CCDC39 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV56491676; called by muse, mutect2
- CCDC68 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100491996; called by muse, mutect2
- CCDC88A | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55060055; called by muse, mutect2
- CCDC88B | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 13/111 reads (12%) | catalogued as rs1210838474; called by muse, mutect2, varscan2
- CD70 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs755905794, COSV55565732; called by muse, mutect2, varscan2
- CDC14C | c.1489G>T p.D497Y (on ENST00000428251; = p.D390Y on NM_152627.3) | Missense Mutation (SNP) | VAF 70/370 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs765363567; called by muse, mutect2, varscan2
- CDCA2 | c.1273G>C p.D425H | Missense Mutation (SNP) | VAF 40/324 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV57948524; called by muse, mutect2, varscan2
- CDH9 | c.1883T>C p.I628T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV50489337; called by muse, varscan2
- CENPJ | c.3772G>A p.D1258N | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); catalogued as COSV99693768; called by muse, varscan2
- CEP170B | c.4288G>C p.E1430Q (on ENST00000453495; = p.E1359Q on NM_015005.3) | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); catalogued as COSV52044811; called by muse, mutect2, varscan2
- CFB | c.1856-7C>T | Splice Region (SNP) | VAF 45/306 reads (15%) | catalogued as rs757245217; called by muse, mutect2, varscan2
- CHPF2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs200584804; called by muse, mutect2
- CHST4 | c.841C>G p.R281G | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs188876913, COSV58298553; called by muse, mutect2, varscan2
- CNTN5 | c.3063C>G p.S1021R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.583); catalogued as COSV99681694; called by muse, varscan2
- COG8 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs763216085; called by muse, mutect2, varscan2
- COL14A1 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 23/278 reads (8%) | catalogued as COSV52850420; called by muse, mutect2
- COL4A5 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1401898740; called by muse, mutect2, varscan2
- COL6A5 | c.3430G>A p.D1144N | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as COSV99594426; called by muse, mutect2, varscan2
- CRIM1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 104/711 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as rs764933162; called by muse, mutect2, varscan2
- CRNKL1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.789); catalogued as COSV55640178; called by muse, mutect2
- CSMD3 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99833549, COSV99836169; called by muse, mutect2, varscan2
- CSNK1G3 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV62054676; called by muse, mutect2, varscan2
- CTAGE9 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 67/682 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs543656207; called by muse, mutect2, varscan2
- CXXC5 | c.953T>A p.F318Y | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1279236037; called by muse, mutect2, varscan2
- DCAF11 | c.1121C>G p.S374C | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as rs1300269344; called by muse, mutect2, varscan2
- DCAF5 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs1440473240, COSV58458229; called by muse, mutect2
- DCD | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as rs199541255; called by muse, mutect2
- DCDC1 | c.3781C>G p.Q1261E (on ENST00000597505 / NM_001367979.1; = p.Q368E on NM_020869.3) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57999270; called by muse, mutect2
- DCLRE1B | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56724146; called by muse, mutect2
- DGCR2 | c.1138G>A p.E380K | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs775108492, COSV54218113; called by muse, mutect2, varscan2
- DLAT | c.495C>G p.I165M | Missense Mutation (SNP) | VAF 78/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54771246; called by muse, mutect2, varscan2
- DNAH10 | c.4078G>C p.E1360Q (on ENST00000409039; = p.E1299Q on NM_207437.3) | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV101292074; called by muse, mutect2
- DNASE1L2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 90/451 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1396071357; called by muse, mutect2, varscan2
- DOC2B | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.009); catalogued as COSV59095847; called by muse, mutect2, varscan2
- DSC1 | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1194876741; called by mutect2, varscan2
- DSC1 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 15/97 reads (15%) | catalogued as COSV57146558; called by muse, mutect2, varscan2
- DTNA | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV52028519; called by muse, mutect2, varscan2
- DYNC1H1 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 36/577 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV100794145, COSV64139081; called by muse, mutect2
- EEF2K | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs775963419, COSV53787474; called by muse, mutect2, varscan2
- EFCAB7 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs765217503; called by muse, mutect2
- EGR4 | c.827A>G p.Y276C (on ENST00000545030; = p.Y173C on NM_001965.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as rs1356644804; called by muse, mutect2
- EHBP1L1 | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs556715013, COSV58573831; called by muse, mutect2, varscan2
- EHBP1L1 | c.3770C>T p.S1257L | Missense Mutation (SNP) | VAF 74/395 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); catalogued as rs1252380847; called by muse, mutect2, varscan2
- EP300 | c.5809G>C p.E1937Q | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.056); catalogued as COSV54343084, COSV54343892; called by muse, mutect2, varscan2
- ERGIC1 | c.125C>T p.S42L | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs574989589; called by muse, mutect2, varscan2
- EVPL | c.4960G>A p.E1654K | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs765962455; called by muse, mutect2, varscan2
- FCHO1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs767788386; called by muse, mutect2, varscan2
- FEM1C | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.214); catalogued as COSV57232542; called by muse, mutect2, varscan2
- FEZF2 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs1452224683; called by muse, mutect2, varscan2
- FJX1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 49/579 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100502797, COSV58553013; called by muse, mutect2
- FLII | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 63/350 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs760997501; called by muse, mutect2, varscan2
- FOCAD | c.4551G>A p.M1517I | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV100620765; called by muse, mutect2, varscan2
- FRAS1 | c.7032C>T p.A2344= | Splice Region (SNP) | VAF 12/62 reads (19%) | catalogued as rs373354213; called by muse, mutect2
- FRMPD1 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs138526022, COSV66700528; called by muse, mutect2, varscan2
- FSCB | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.598); catalogued as rs772394093; called by muse, mutect2, varscan2
- GABRA3 | c.263-1G>A p.X88_splice | Splice Site (SNP) | VAF 13/106 reads (12%) | catalogued as COSV64799050; called by muse, mutect2, varscan2
- GATA4 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 93/602 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.249); catalogued as rs1380093426; called by muse, mutect2, varscan2
- GLUD2 | c.564C>G p.I188M | Missense Mutation (SNP) | VAF 85/290 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV60152436; called by muse, mutect2, varscan2
- GRK7 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as rs576881901, COSV53822451, COSV53826585; called by muse, mutect2, varscan2
- GRM1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 76/416 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51128372; called by muse, mutect2, varscan2
- GRM1 | c.2144G>T p.S715I | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs1418199343; called by muse, mutect2, varscan2
- GRM5 | c.1571G>C p.R524P | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV59621000; called by muse, mutect2, varscan2
- GSTM2 | c.617G>A p.R206K | Missense Mutation (SNP) | VAF 108/629 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs527715023; called by muse, mutect2, varscan2
- HELLS | c.2392G>C p.E798Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV53298762; called by muse, mutect2, varscan2
- HERC2 | c.10411G>C p.E3471Q | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.475); catalogued as COSV99874246; called by muse, mutect2, varscan2
- HOOK2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.734); catalogued as rs371831614; called by muse, mutect2, varscan2
- HOXD1 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV58924422; called by muse, mutect2, varscan2
- HUWE1 | c.12529G>A p.E4177K | Missense Mutation (SNP) | VAF 100/264 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53351298; called by muse, mutect2, varscan2
- IFNA4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 38/533 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.262); catalogued as rs912620310; called by muse, mutect2
- IFT57 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52708608; called by muse, mutect2, varscan2
- IL1RAPL1 | c.912-1G>C p.X304_splice | Splice Site (SNP) | VAF 38/114 reads (33%) | catalogued as COSV56239790, COSV56246551; called by muse, mutect2, varscan2
- IL27RA | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.092); catalogued as COSV54600233; called by muse, mutect2, varscan2
- INSR | c.3361G>C p.E1121Q | Missense Mutation (SNP) | VAF 88/591 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV57167159; called by muse, mutect2, varscan2
- IQGAP2 | c.1921G>C p.E641Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57171965, COSV57181795; called by muse, mutect2
- IRGQ | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 80/481 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.622); catalogued as COSV60670980; called by muse, mutect2, varscan2
- ITGAE | c.876C>G p.I292M | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99560357; called by muse, mutect2, varscan2
- KCNAB1 | c.604G>A p.E202K (on ENST00000490337 / NM_172160.3; = p.E191K on NM_003471.3) | Missense Mutation (SNP) | VAF 51/386 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs377328629, COSV100204307, COSV56743821; called by muse, mutect2, varscan2
- KCNK2 | c.67G>A p.D23N (on ENST00000444842 / NM_001017425.3; = p.D8N on NM_014217.4) | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as rs987575483; called by muse, mutect2, varscan2
- KDM1B | c.1678G>A p.D560N (on ENST00000449850; = p.D328N on NM_153042.4) | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV99924234; called by muse, mutect2, varscan2
- KIF26A | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1243308568, COSV59468781; called by muse, mutect2, varscan2
- KLHL17 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1489601479; called by muse, mutect2
- KLHL6 | c.1781G>C p.R594P | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58067455; called by muse, mutect2, varscan2
- KNOP1 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV54928960; called by muse, mutect2, varscan2
- LRP1B | c.2582G>T p.R861L | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100796619; called by muse, mutect2, varscan2
- LRP1B | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV67203355; called by muse, mutect2, varscan2
- LRRC4C | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV53418301, COSV99538823; called by muse, mutect2, varscan2
- LRRK1 | c.1156G>C p.D386H | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52611977; called by muse, mutect2, varscan2
- LY75 | c.4127G>T p.S1376I | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV55106219, COSV99716575; called by muse, varscan2
- MARCO | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/155 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs570068996, COSV59057747; called by muse, mutect2, varscan2
- MDFI | c.504C>G p.I168M | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV100025675; called by muse, mutect2, varscan2
- METTL11B | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63029895; called by muse, mutect2
- MFSD9 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 78/494 reads (16%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.042); catalogued as rs762045089, COSV51492729, COSV99302119, COSV99302265; called by muse, mutect2, varscan2
- MGAM2 | c.4081C>T p.R1361* | Nonsense Mutation (SNP) | VAF 22/238 reads (9%) | catalogued as rs1038932026, COSV72177167; called by muse, mutect2
- MLF2 | c.270+3G>A | Splice Region (SNP) | VAF 36/302 reads (12%) | catalogued as rs111280582; called by muse, mutect2, varscan2
- MRTFB | c.1820G>T p.R607L | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57958164; called by muse, mutect2, varscan2
- MUC1 | c.3004C>T p.P1002S (on ENST00000611571 / NM_001371720.1; = p.P215S on NM_001204285.2) | Missense Mutation (SNP) | VAF 76/399 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.856); catalogued as rs1397185072; called by muse, mutect2, varscan2
- MUC7 | c.425G>C p.R142T | Missense Mutation (SNP) | VAF 43/365 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs781643884, COSV59217381; called by muse, mutect2, varscan2
- MYH9 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 139/806 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV53381501; called by muse, mutect2, varscan2
- MYO16 | c.2324G>C p.G775A | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV51777640; called by muse, mutect2, varscan2
- MYO1F | c.2004G>C p.Q668H | Missense Mutation (SNP) | VAF 93/491 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100596331; called by muse, varscan2
- MYO7B | c.1709G>C p.R570P | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs371153674; called by muse, mutect2, varscan2
- MYO9B | c.4851G>C p.Q1617H | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs760750887; called by muse, mutect2, varscan2
- MZF1 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758000217; called by muse, mutect2
- NES | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 84/478 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.583); catalogued as rs747226593; called by muse, mutect2, varscan2
- NFATC1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 50/313 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs372492742; called by muse, mutect2, varscan2
- NFATC1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs149308374; called by muse, mutect2, varscan2
- NLRP5 | c.3297C>T p.L1099= | Splice Region (SNP) | VAF 14/89 reads (16%) | catalogued as rs187087702, COSV66761796; called by muse, mutect2, varscan2
- NLRP9 | c.2662G>C p.E888Q | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.222); catalogued as rs780476740, COSV100243348; called by muse, mutect2, varscan2
- NOS3 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.969); catalogued as COSV99871816; called by muse, mutect2
- NUBPL | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs35433432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NUP88 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.637); catalogued as COSV56706375; called by muse, mutect2, varscan2
- OR2L3 | c.180C>G p.F60L | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV63454535; called by muse, mutect2, varscan2
- OR4K14 | c.605C>A p.S202* | Nonsense Mutation (SNP) | VAF 42/491 reads (9%) | catalogued as COSV59292821; called by muse, mutect2
- OTOGL | c.6967C>T p.R2323* (on ENST00000547103; = p.R2314* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 40/218 reads (18%) | catalogued as rs749602353, COSV54022699; called by muse, mutect2, varscan2
- OXCT1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 89/593 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs201384699; called by muse, mutect2, varscan2
- P2RX2 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.878); catalogued as COSV57683724; called by muse, mutect2, varscan2
- PAQR9 | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 71/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1220331008, COSV61418324; called by muse, mutect2, varscan2
- PARP11 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs769972983, COSV99958730; called by muse, mutect2, varscan2
- PCDH15 | c.1991C>G p.S664* | Nonsense Mutation (SNP) | VAF 33/200 reads (17%) | catalogued as COSV57381049; called by muse, mutect2, varscan2
- PCDHA2 | c.2388+7C>G | Splice Region (SNP) | VAF 46/237 reads (19%) | catalogued as rs782499086; called by muse, mutect2, varscan2
- PCDHB1 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 59/226 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV60629945; called by muse, mutect2, varscan2
- PDZRN4 | c.2401G>T p.G801C (on ENST00000402685 / NM_001164595.2; = p.G543C on NM_013377.4) | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as rs765762946; called by muse, mutect2, varscan2
- PEX11A | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 19/86 reads (22%) | catalogued as COSV55582698; called by muse, mutect2, varscan2
- PHPT1 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56034068; called by muse, mutect2, varscan2
- PHTF2 | c.338G>A p.R113K (on ENST00000248550 / NM_001366089.1; = p.R75K on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.438); catalogued as COSV50338987; called by muse, mutect2, varscan2
- PIK3R4 | c.3589C>G p.Q1197E | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.449); catalogued as rs1258797285, COSV63240846; called by muse, mutect2, varscan2
- PIP4K2A | c.69C>A p.F23L | Missense Mutation (SNP) | VAF 49/322 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs748177306, COSV64863669; called by muse, mutect2, varscan2
- PLEC | c.12337G>A p.V4113I (on ENST00000322810 / NM_201380.4; = p.V4003I on NM_000445.5) | Missense Mutation (SNP) | VAF 100/606 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.12); catalogued as rs782422260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.10182C>G p.I3394M (on ENST00000322810 / NM_201380.4; = p.I3284M on NM_000445.5) | Missense Mutation (SNP) | VAF 120/855 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV59598828; called by muse, mutect2, varscan2
- PLEKHO2 | c.945G>C p.K315N | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60262090; called by muse, mutect2, varscan2
- PLIN1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs867311523; called by muse, mutect2, varscan2
- POTEF | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 120/1174 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100665401; called by muse, mutect2
- PREB | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 52/308 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs745551331; called by muse, varscan2
- PRKAR2A | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 42/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55554596; called by muse, mutect2, varscan2
- PSG4 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs754251695; called by muse, mutect2, varscan2
- PSMG3 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99365888, COSV99365897; called by muse, mutect2, varscan2
- PUM1 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs200827919; called by muse, mutect2, varscan2
- RANBP2 | c.9305G>C p.G3102A | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51696455; called by mutect2, varscan2
- REPS2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100381853; called by muse, mutect2, varscan2
- RGPD8 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 68/509 reads (13%) | catalogued as COSV56902477; called by muse, mutect2, varscan2
- RHOBTB1 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 53/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs367901643; called by muse, mutect2, varscan2
- RNF166 | c.315G>C p.V105= | Splice Region (SNP) | VAF 22/95 reads (23%) | catalogued as rs746065959; called by muse, mutect2, varscan2
- RSPRY1 | c.1302G>C p.L434F | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101070977; called by muse, mutect2, varscan2
- RYR2 | c.11695G>T p.D3899Y | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100769351; called by muse, mutect2, varscan2
- SALL3 | c.3861C>G p.F1287L | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV73306334; called by muse, varscan2
- SCAF1 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as rs772873507; called by muse, mutect2, varscan2
- SCARB2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796052947, COSV53669567; ClinVar: uncertain significance; called by muse, mutect2
- SCN3A | c.1553G>C p.G518A | Missense Mutation (SNP) | VAF 76/515 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.051); catalogued as COSV51830293; called by muse, mutect2, varscan2
- SCN8A | c.3417C>G p.I1139M | Missense Mutation (SNP) | VAF 65/349 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.924); catalogued as rs1183713398; called by muse, mutect2, varscan2
- SEC24B | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532212635, COSV54497189; called by muse, mutect2, varscan2
- SHOC1 | c.2468G>A p.C823Y | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV59507829; called by muse, mutect2
- SKIDA1 | c.2423G>A p.R808H | Missense Mutation (SNP) | VAF 30/212 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV71610447; called by muse, mutect2, varscan2
- SLC46A2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 78/405 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773075636; called by muse, mutect2, varscan2
- SMC2 | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.14); catalogued as rs758995648; called by muse, mutect2, varscan2
- SNX21 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 82/405 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100701743; called by muse, mutect2, varscan2
- SON | c.3281C>T p.S1094L | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs750627493, COSV51664474; called by muse, mutect2, varscan2
- SPEN | c.8713G>A p.D2905N | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1456771008, COSV65358945; called by muse, mutect2, varscan2
- SPRED1 | c.869C>G p.S290* | Nonsense Mutation (SNP) | VAF 58/359 reads (16%) | catalogued as COSV100136536; called by muse, mutect2, varscan2
- SSC5D | c.3082C>G p.R1028G | Missense Mutation (SNP) | VAF 61/435 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs750780205; called by muse, mutect2, varscan2
- STAB2 | c.5932G>C p.D1978H | Missense Mutation (SNP) | VAF 59/310 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV101185877; called by muse, mutect2, varscan2
- STAT2 | c.2348C>G p.S783* | Nonsense Mutation (SNP) | VAF 58/291 reads (20%) | catalogued as COSV57335984; called by muse, mutect2, varscan2
- SUPT6H | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.255); catalogued as COSV58930450, COSV58931140; called by muse, mutect2
- SYNE2 | c.1988C>T p.S663L | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100648236, COSV59953939; called by muse, mutect2
- TAF6L | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs12514; called by muse, mutect2, varscan2
- TEAD3 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV58818198; called by muse, mutect2
- TEDC1 | c.1054G>A p.E352K (on ENST00000392523 / NM_001367178.1; = p.E283K on NM_001134875.1) | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as rs781881820, COSV58155940; called by muse, mutect2, varscan2
- TFAP2A | c.931G>A p.E311K (on ENST00000482890; = p.E303K on NM_001032280.3) | Missense Mutation (SNP) | VAF 57/469 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs756122879, COSV100117071; called by muse, mutect2, varscan2
- TFAP2A | c.746C>G p.S249W (on ENST00000482890; = p.S241W on NM_001032280.3) | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as CM110104, CM113567, COSV60237165; called by muse, mutect2, varscan2
- THOC1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV55274604; called by muse, mutect2, varscan2
- TMA7 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 48/576 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs1443626455; called by muse, mutect2
- TMEM151A | c.864C>G p.F288L | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59174313; called by muse, mutect2, varscan2
- TMEM208 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs199532825; called by muse, mutect2, varscan2
- TMEM237 | c.701G>C p.G234A (on ENST00000409883 / NM_001044385.3; = p.G226A on NM_152388.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53804447, COSV53806189; called by muse, mutect2
- TNR | c.835G>C p.G279R | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs751249645, COSV99688412; called by muse, mutect2, varscan2
- TOB1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 39/203 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs1380916549, COSV52151052; called by muse, mutect2, varscan2
- TOPORS | c.2291A>T p.Y764F | Missense Mutation (SNP) | VAF 104/262 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); catalogued as COSV100859589; called by muse, mutect2, varscan2
- TRBV5-1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs1264030879; called by muse, mutect2
- TRIO | c.8924C>T p.T2975M | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.231); catalogued as rs188618696; called by muse, mutect2, varscan2
- TRIP11 | c.5839C>T p.L1947F | Missense Mutation (SNP) | VAF 46/697 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99970509; called by muse, mutect2
- TSEN15 | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62294463; called by muse, mutect2, varscan2
- TSPAN10 | c.285G>C p.L95F (on ENST00000574882 / NM_001290212.1; = p.L57F on NM_031945.4) | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.314); catalogued as COSV60773892; called by muse, mutect2, varscan2
- TTC3 | c.3313C>G p.Q1105E | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.388); catalogued as COSV61294577; called by muse, mutect2, varscan2
- TTN | c.16042C>T p.P5348S (on ENST00000591111; = p.P4421S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | PolyPhen probably damaging (0.998); catalogued as rs775278050, COSV60218706; called by muse, mutect2, varscan2
- UBE2O | c.839C>G p.S280* | Nonsense Mutation (SNP) | VAF 38/345 reads (11%) | catalogued as rs75444317; called by muse, mutect2, varscan2
- UBXN1 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 79/468 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1255542332; called by muse, mutect2, varscan2
- UGGT1 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs761159782, COSV99390514; called by muse, mutect2, varscan2
- UNC13A | c.487C>A p.Q163K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs748615592; called by muse, mutect2, varscan2
- UNC5D | c.2746G>C p.D916H | Missense Mutation (SNP) | VAF 90/689 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99777339; called by muse, mutect2, varscan2
- UNC80 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.037); catalogued as rs1367845027; called by muse, mutect2, varscan2
- VCPIP1 | c.3042G>C p.K1014N | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV60046224; called by muse, mutect2
- VCPIP1 | c.2806G>A p.D936N | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60048196; called by muse, mutect2
- WWTR1 | c.185C>G p.S62W | Missense Mutation (SNP) | VAF 92/571 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62292132; called by muse, mutect2, varscan2
- ZFHX4 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs1405979515, COSV50521139; called by muse, mutect2, varscan2
- ZFP28 | c.2339C>T p.S780F | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56737174, COSV56737716; called by muse, mutect2, varscan2
- ZFP41 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV58087961; called by muse, mutect2
- ZGRF1 | c.5714G>A p.R1905Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs574383993; called by muse, mutect2
- ZNF445 | c.2165C>T p.S722L | Missense Mutation (SNP) | VAF 86/569 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV101253740; called by muse, mutect2, varscan2
- ZNF501 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV101247181; called by muse, mutect2, varscan2
- ZNF536 | c.2526C>A p.F842L | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV62829648; called by muse, mutect2, varscan2
- ZNF560 | c.1096C>G p.H366D | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV56872149; called by muse, mutect2, varscan2
- ZNF716 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); catalogued as rs781956725; called by muse, mutect2, varscan2
- ZNF804B | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV100305251, COSV60826741; called by muse, mutect2, varscan2
- ZNF808 | c.1319C>G p.S440* | Nonsense Mutation (SNP) | VAF 52/196 reads (27%) | catalogued as rs765318232; called by muse, mutect2, varscan2
- ZNF99 | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 63/443 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.296); catalogued as rs780047521; called by muse, mutect2, varscan2
- AARS1 | c.2324C>G p.S775C | Missense Mutation (SNP) | VAF 98/568 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- ABCA13 | c.14751G>T p.E4917D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ABCA13 | c.14752G>T p.E4918* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- ABCF1 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 31/441 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); called by muse, mutect2
- ABRAXAS2 | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC011462.1 | c.343G>T p.V115F | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- AC098582.1 | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- AC098582.1 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ACO1 | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACY1 | c.707+3G>C | Splice Region (SNP) | VAF 39/525 reads (7%) | called by muse, mutect2
- ADAMTS9 | c.3612G>A p.M1204I | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- ADGRG4 | c.5718G>T p.E1906D | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.3901G>T p.D1301Y | Missense Mutation (SNP) | VAF 56/357 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGK | c.1238G>C p.R413T | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- AHNAK2 | c.10306C>G p.L3436V | Missense Mutation (SNP) | VAF 64/748 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2
- AJUBA | c.164dup p.P56Tfs*4 | Frame Shift Ins (INS) | VAF 46/179 reads (26%) | called by mutect2, pindel, varscan2
- AKAP4 | c.1330C>T p.Q444* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- ALMS1 | c.11576C>G p.S3859C | Missense Mutation (SNP) | VAF 45/271 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- AMFR | c.155C>G p.S52W | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ANAPC1 | c.1565C>G p.S522C | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ANK1 | c.613-1G>A p.X205_splice | Splice Site (SNP) | VAF 94/550 reads (17%) | called by muse, mutect2, varscan2
- ANK2 | c.6253G>C p.E2085Q | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ANK3 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ANK3 | c.415-1G>C p.X139_splice | Splice Site (SNP) | VAF 24/123 reads (20%) | called by muse, mutect2, varscan2
- ANKRD11 | c.3740C>G p.A1247G | Missense Mutation (SNP) | VAF 86/517 reads (17%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ANKRD36 | c.1764G>A p.K588= | Splice Region (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- ANKS3 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ANKUB1 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ANXA5 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- APC2 | c.4484C>T p.S1495L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- APEH | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 48/524 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2
- APOH | c.601_602insT p.R201Mfs*29 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | called by mutect2, pindel
- ARAF | c.1269G>C p.K423N | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ARAP2 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2
- ARHGAP11A | c.1246G>A p.G416R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP35 | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ARHGEF15 | c.1741C>T p.Q581* | Nonsense Mutation (SNP) | VAF 36/217 reads (17%) | called by muse, mutect2, varscan2
- ARHGEF16 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 69/381 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ARIH1 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 26/223 reads (12%) | called by muse, mutect2, varscan2
- ARMCX2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASH1L | c.4974G>C p.Q1658H | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- ATG4C | c.161-1G>C p.X54_splice | Splice Site (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- ATP5F1A | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ATP6V0A4 | c.1651del p.Q551Rfs*30 | Frame Shift Del (DEL) | VAF 65/489 reads (13%) | called by mutect2, pindel, varscan2
- B3GLCT | c.1003C>G p.L335V | Missense Mutation (SNP) | VAF 15/216 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.211); called by muse, mutect2
- B3GNT4 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- BAZ2B | c.6367G>T p.E2123* | Nonsense Mutation (SNP) | VAF 32/216 reads (15%) | called by muse, mutect2, varscan2
- BICD2 | c.1753C>G p.L585V | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- BLVRA | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 57/391 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- C10orf90 | c.1415G>C p.R472P | Missense Mutation (SNP) | VAF 49/431 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- C2orf16 | c.4531C>T p.Q1511* | Nonsense Mutation (SNP) | VAF 31/377 reads (8%) | called by muse, mutect2
- C8orf37 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C8orf37 | c.375-1G>C p.X125_splice | Splice Site (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- C8orf58 | c.137G>C p.W46S | Missense Mutation (SNP) | VAF 47/611 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.428); called by muse, mutect2
- CABIN1 | c.4151C>G p.S1384* | Nonsense Mutation (SNP) | VAF 101/628 reads (16%) | called by muse, mutect2, varscan2
- CACNA1G | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.129); called by muse, mutect2
- CAMSAP1 | c.4322G>A p.S1441N | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASD1 | c.695A>G p.Y232C | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CATSPER3 | c.630G>C p.W210C | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAVIN4 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCAR2 | c.1877C>G p.S626C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2
- CCDC152 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2
- CCDC81 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- CCT7 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- CD151 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 55/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CDRT1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CEL | c.1381G>A p.D461N (on ENST00000673714; = p.D458N on NM_001807.6) | Missense Mutation (SNP) | VAF 60/356 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- CENPF | c.9238C>G p.P3080A | Missense Mutation (SNP) | VAF 80/458 reads (17%) | SIFT tolerated (0.99); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CENPM | c.321G>C p.E107D | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CENPQ | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP97 | c.1725G>T p.R575S | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CFAP157 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- CHCHD3 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 21/241 reads (9%) | called by muse, mutect2
- CHD7 | c.2255G>C p.R752T | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CHIA | c.564C>G p.I188M (on ENST00000343320; = p.I80M on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.193); called by muse, mutect2
- CHPT1 | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.304); called by mutect2, varscan2
- CLCA1 | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 54/253 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLEC10A | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CLIC2 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- CMTR1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 28/240 reads (12%) | called by muse, mutect2, varscan2
- COL6A5 | c.4071C>G p.F1357L | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COMMD4P2 | n.136G>C | Splice Region (SNP) | VAF 12/66 reads (18%) | called by mutect2, varscan2
- CPSF2 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- CPXCR1 | c.191C>G p.P64R | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- CR1L | c.1389G>C p.W463C | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSF1 | c.475C>G p.L159V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- CSF1 | c.1585C>T p.Q529* | Nonsense Mutation (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- CTDSPL | c.538G>A p.D180N (on ENST00000273179 / NM_001008392.2; = p.D169N on NM_005808.3) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); called by muse, mutect2
- CXCR6 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 44/386 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DAG1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 119/656 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DBR1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 38/253 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DECR1 | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND4C | c.1327C>T p.Q443* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2
- DEPP1 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- DICER1 | c.4477C>T p.P1493S | Missense Mutation (SNP) | VAF 116/517 reads (22%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- DNAH10 | c.4007del p.K1336Rfs*15 (on ENST00000409039; = p.K1275Rfs*15 on NM_207437.3) | Frame Shift Del (DEL) | VAF 18/131 reads (14%) | called by mutect2, pindel, varscan2
- DNAH9 | c.3673C>T p.Q1225* | Nonsense Mutation (SNP) | VAF 43/242 reads (18%) | called by muse, mutect2, varscan2
- DOP1A | c.6469C>G p.Q2157E | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- DPRX | c.305G>A p.R102K | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DRP2 | c.1699-1G>C p.X567_splice | Splice Site (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- DSCC1 | c.634C>T p.Q212* | Nonsense Mutation (SNP) | VAF 14/221 reads (6%) | called by muse, mutect2
- DSP | c.4921G>C p.D1641H | Missense Mutation (SNP) | VAF 66/316 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- DYNC1H1 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 40/427 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- DZIP1 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- EGF | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 42/461 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2
- EIF2S3 | c.237C>G p.I79M | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- EIF4A2 | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ELOA3B | c.884C>G p.A295G | Missense Mutation (SNP) | VAF 213/3303 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.279); called by muse, mutect2
- EOGT | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 27/232 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA2 | c.1846_1852del p.Q616* | Frame Shift Del (DEL) | VAF 66/484 reads (14%) | called by mutect2, pindel
- EPHA2 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 69/471 reads (15%) | called by muse, mutect2, varscan2
- ESAM | c.547G>T p.V183F | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, varscan2
- EYS | c.6816G>C p.E2272D | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- F12 | c.1390C>G p.L464V | Missense Mutation (SNP) | VAF 92/405 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FAM111B | c.1132C>G p.L378V | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT1 | c.10192C>G p.L3398V | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT1 | c.6661_6662dup p.D2222Efs*19 | Frame Shift Ins (INS) | VAF 25/100 reads (25%) | called by mutect2, pindel, varscan2
- FDXACB1 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 13/201 reads (6%) | called by muse, mutect2
- FER1L6 | c.1529del p.G510Efs*3 | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel, varscan2
- FIZ1 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 106/569 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FLT4 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FLT4 | c.1418G>T p.S473I | Missense Mutation (SNP) | VAF 60/325 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- FRAS1 | c.9001G>C p.E3001Q | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FREM3 | c.6061C>T p.H2021Y | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.138); called by muse, varscan2
- FSTL5 | c.2375C>A p.P792H | Missense Mutation (SNP) | VAF 14/173 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- FYCO1 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 154/1192 reads (13%) | called by muse, mutect2, varscan2
- FYCO1 | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 64/508 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.278); called by muse, varscan2
- GALNT2 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 67/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GAS8 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- GJA9 | c.937C>G p.H313D | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- GNAL | c.164G>C p.R55P | Missense Mutation (SNP) | VAF 81/502 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- GNAL | c.940G>A p.D314N (on ENST00000269162 / NM_001142339.3; = p.D391N on NM_182978.4) | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- GOLGA2 | c.2806G>C p.E936Q | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- GOLGB1 | c.9292C>G p.Q3098E | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- GRM5 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GUCY1A1 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAUS3 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- HAUS6 | c.1062G>C p.M354I | Missense Mutation (SNP) | VAF 19/200 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HERPUD2 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HHIPL1 | c.1768C>G p.Q590E | Missense Mutation (SNP) | VAF 47/438 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- HIPK1 | c.2965C>G p.P989A | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HMGA2 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 66/351 reads (19%) | called by muse, mutect2, varscan2
- HPS5 | c.661G>A p.A221T (on ENST00000349215 / NM_181507.2; = p.A107T on NM_007216.4) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFNL3 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- IGHG4 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 35/246 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- INPP5B | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 51/344 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KANSL1 | c.2725G>T p.E909* (on ENST00000574590 / NM_001193465.2; = p.E910* on NM_015443.4) | Nonsense Mutation (SNP) | VAF 39/210 reads (19%) | called by muse, varscan2
- KANSL1 | c.2724T>A p.I908= (on ENST00000574590 / NM_001193465.2; = p.I909= on NM_015443.4) | Splice Region (SNP) | VAF 40/212 reads (19%) | called by muse, varscan2
- KAT6A | c.5917C>T p.H1973Y | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- KCNH7 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- KCNJ3 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KDM3A | c.3797C>T p.S1266F | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM5A | c.779-1G>A p.X260_splice | Splice Site (SNP) | VAF 55/383 reads (14%) | called by muse, mutect2, varscan2
- KIAA0825 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF16B | c.3918A>C p.K1306N | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KNDC1 | c.3929C>G p.S1310W | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KRT34 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KRT6A | c.1029G>C p.E343D | Missense Mutation (SNP) | VAF 152/818 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LAMC1 | c.4120G>C p.D1374H | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- LARP7 | c.154C>T p.H52Y | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LONP1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 59/557 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LONP2 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRIG2 | c.2830G>C p.E944Q | Missense Mutation (SNP) | VAF 70/333 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LYPLA2 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 26/454 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- MAGEL2 | c.1220C>A p.P407Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- MAN2A2 | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MAP1B | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 72/352 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP1B | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MBD5 | c.3466G>T p.G1156C | Missense Mutation (SNP) | VAF 120/411 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MBD5 | c.3467G>T p.G1156V | Missense Mutation (SNP) | VAF 119/412 reads (29%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MEGF10 | c.2697G>A p.M899I | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MFSD14A | c.1008G>A p.M336I | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.627); called by muse, mutect2
- MGAT3 | c.1426G>C p.D476H | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MICAL1 | c.2529C>A p.H843Q | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MICAL3 | c.2836G>A p.E946K | Missense Mutation (SNP) | VAF 52/309 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.079); called by muse, varscan2
- MLH1 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 48/379 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MRPL3 | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2
- MUC16 | c.11123C>T p.S3708L | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MUC4 | c.16220C>G p.S5407* (on ENST00000463781 / NM_018406.7; = p.S1171* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2, varscan2
- MYCBP2 | c.3458C>T p.A1153V (on ENST00000357337; = p.A1191V on NM_015057.5) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- MYH1 | c.5170-1G>A p.X1724_splice | Splice Site (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- MYH2 | c.205A>T p.T69S | Missense Mutation (SNP) | VAF 72/523 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYORG | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NALCN | c.3568C>T p.L1190F | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- NBPF26 | c.4159G>A p.D1387N (on ENST00000620612; = p.D1125N on NM_001351372.1) | Missense Mutation (SNP) | VAF 106/330 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.906); called by muse, varscan2
- NCKAP5 | c.2143C>T p.Q715* | Nonsense Mutation (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- NCOA2 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NDST3 | c.959G>A p.R320K | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NF2 | c.1659G>C p.E553D | Missense Mutation (SNP) | VAF 87/440 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- NIBAN3 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- NLRP14 | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 97/492 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- NPR1 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- NPRL3 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 37/283 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NSD1 | c.1505G>A p.S502N | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NUDT5 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 52/354 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OGFRL1 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- OLIG1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 92/435 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, varscan2
- OR10G4 | c.215C>G p.S72C | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51G1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR52M1 | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR5H15 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- OR5T3 | c.891G>C p.L297F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- OS9 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTUD4 | c.2956C>T p.Q986* (on ENST00000447906 / NM_001366057.1; = p.Q921* on NM_001102653.1) | Nonsense Mutation (SNP) | VAF 17/169 reads (10%) | called by muse, mutect2
- OTULINL | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- OVCH2 | c.1580C>G p.S527* | Nonsense Mutation (SNP) | VAF 20/244 reads (8%) | called by muse, mutect2
- PARP14 | c.5029G>C p.E1677Q | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDCD4 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PDE1A | c.1270A>G p.I424V | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- PELI3 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 26/170 reads (15%) | called by muse, mutect2, varscan2
- PGBD4 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- PGLYRP4 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 63/435 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PHF2 | c.2912C>G p.S971C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- PHLDB2 | c.2342G>A p.R781K (on ENST00000393925 / NM_001134439.2; = p.R738K on NM_145753.2) | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- PIGA | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3R3 | c.772A>T p.M258L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, varscan2
- PKP1 | c.307-1G>A p.X103_splice | Splice Site (SNP) | VAF 66/385 reads (17%) | called by muse, mutect2, varscan2
- PKP1 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 85/528 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PKP4 | c.2141G>A p.C714Y | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCE1 | c.3712G>C p.D1238H | Missense Mutation (SNP) | VAF 40/626 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLCH2 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXNB2 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- POLD1 | c.2721G>A p.M907I | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- POLDIP2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POTEF | c.2328C>G p.I776M | Missense Mutation (SNP) | VAF 138/1051 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- PPFIA2 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PREB | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PREP | c.991C>T p.Q331* (on ENST00000369110; = p.Q397* on NM_002726.5) | Nonsense Mutation (SNP) | VAF 47/228 reads (21%) | called by muse, mutect2, varscan2
- PRKAA2 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PRPF40A | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- PRR36 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT tolerated, low confidence (0.07); called by muse, varscan2
- PRR36 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- PRRC2B | c.4624G>A p.E1542K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PSMD14 | c.265C>G p.P89A | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PTGFR | c.798+2T>C p.X266_splice | Splice Site (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- PTPRH | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- RAB26 | c.534+5G>A | Splice Region (SNP) | VAF 25/119 reads (21%) | called by muse, mutect2, varscan2
- RANBP2 | c.2484G>C p.L828F | Missense Mutation (SNP) | VAF 26/556 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- RAP1GDS1 | c.337C>G p.L113V (on ENST00000408927 / NM_001100427.2; = p.L114V on NM_021159.5) | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RASGRP3 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RGL4 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNASE3 | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- RNF157 | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF17 | c.1945G>T p.A649S | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- RNF38 | c.817C>G p.L273V | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RNF5 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- ROBO4 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ROR1 | c.521G>C p.R174T | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RPAP2 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- RPL10 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 79/312 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RREB1 | c.2611C>T p.H871Y | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.412); called by muse, mutect2
- S1PR1 | c.546G>C p.W182C | Missense Mutation (SNP) | VAF 76/390 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SARS1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2
- SAXO1 | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SEC24C | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SEMA4D | c.2306C>G p.S769W | Missense Mutation (SNP) | VAF 57/392 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SERPINA5 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB13 | c.214_217del p.E72Kfs*3 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- SF3A2 | c.141G>A p.M47I | Missense Mutation (SNP) | VAF 49/254 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- SFT2D2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.066); called by muse, mutect2
- SH3BP5 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 98/633 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- SH3YL1 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 63/422 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- SIRT5 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SLC12A4 | c.561C>A p.F187L | Missense Mutation (SNP) | VAF 36/252 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, varscan2
- SLC25A23 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 43/200 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- SLC30A3 | c.93G>A p.K31= | Splice Region (SNP) | VAF 40/325 reads (12%) | called by muse, mutect2, varscan2
- SLC7A3 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2
- SLITRK2 | c.577C>A p.L193I | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMYD1 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 58/468 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SOX6 | c.1430C>G p.S477C (on ENST00000528429 / NM_001145819.2; = p.S436C on NM_017508.3) | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SP1 | c.1210C>T p.Q404* (on ENST00000327443 / NM_138473.3; = p.Q397* on NM_003109.1) | Nonsense Mutation (SNP) | VAF 15/323 reads (5%) | called by muse, mutect2
- SPAG8 | c.1201-3C>T | Splice Region (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- SPDYE1 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 60/830 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); called by muse, mutect2
- SPEN | c.8341G>T p.E2781* | Nonsense Mutation (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- SPIN1 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SPINK8 | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.021); called by muse, mutect2
- SPRR2B | c.210G>C p.K70N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SSB | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- STK38L | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- STOX1 | c.1736G>C p.R579T | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2
- STOX1 | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 44/458 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- STX18 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2
- SUCLG1 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- SULF2 | c.730C>G p.Q244E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2
- SUN2 | c.123-6C>T | Splice Region (SNP) | VAF 68/348 reads (20%) | called by muse, mutect2, varscan2
- SV2B | c.1725C>G p.I575M | Missense Mutation (SNP) | VAF 87/543 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TACC2 | c.6622G>A p.E2208K (on ENST00000334433; = p.E286K on NM_006997.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TAF1A | c.523T>A p.L175I | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TAF4 | c.1679C>G p.S560* | Nonsense Mutation (SNP) | VAF 44/410 reads (11%) | called by mutect2, varscan2
- TEX36 | c.498G>C p.L166F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THADA | c.2350G>C p.D784H | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- THSD4 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.38); called by muse, mutect2
- TINAGL1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 80/449 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLR4 | c.833A>G p.E278G (on ENST00000355622 / NM_138554.5; = p.E238G on NM_003266.4) | Missense Mutation (SNP) | VAF 77/414 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- TMCC3 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 106/604 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TMEM163 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM232 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- TNC | c.5362dup p.S1788Kfs*2 | Frame Shift Ins (INS) | VAF 29/133 reads (22%) | called by mutect2, pindel, varscan2
- TNFAIP8L2 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 16/173 reads (9%) | called by muse, mutect2
- TNPO1 | c.1369G>C p.D457H | Missense Mutation (SNP) | VAF 36/393 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2
- TNRC18 | c.5799G>C p.K1933N | Missense Mutation (SNP) | VAF 49/465 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- TNS1 | c.531C>G p.I177M | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TRAJ40 | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- TRMT1L | c.639_647del p.K213_Y216delinsN | In Frame Del (DEL) | VAF 19/106 reads (18%) | called by mutect2, pindel, varscan2
- TSSK4 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TTC7B | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TUBGCP6 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 66/397 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- UGGT1 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- UPF2 | c.2202G>C p.K734N | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- USP3 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 45/352 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, varscan2
- USP35 | c.572_588del p.Q191Rfs*35 | Frame Shift Del (DEL) | VAF 30/244 reads (12%) | called by mutect2, pindel
- USP8 | c.1958C>G p.S653* | Nonsense Mutation (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- VAT1L | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- VAV2 | c.2401G>A p.A801T | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VCAN | c.3253G>C p.E1085Q | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- VPS35L | c.940G>C p.E314Q | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- VWA5B2 | c.1243G>T p.E415* | Nonsense Mutation (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- VWA8 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WASF3 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- WWC3 | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- WWOX | c.404G>C p.G135A | Missense Mutation (SNP) | VAF 29/343 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WWP2 | c.1387G>A p.V463M | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XDH | c.2950G>C p.E984Q | Missense Mutation (SNP) | VAF 64/460 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- XPOT | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- XYLB | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- YWHAG | c.546C>G p.F182L | Missense Mutation (SNP) | VAF 65/381 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZBTB38 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.463); called by muse, mutect2
- ZBTB40 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.601); called by muse, varscan2
- ZBTB44 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- ZCCHC8 | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 103/555 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC5 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ZFP62 | c.514G>A p.D172N (on ENST00000502412 / NM_001377944.1; = p.D139N on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/312 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF160 | c.1752G>C p.W584C | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ZNF518B | c.2174A>T p.Q725L | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF638 | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- ZNF638 | c.1595G>C p.R532T | Missense Mutation (SNP) | VAF 71/502 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, varscan2
- ZNF79 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ZNF831 | c.824A>G p.D275G | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ZP1 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ZSWIM4 | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, varscan2
- AASDH | c.1743C>G p.L581= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- AC006059.2 | c.189C>G p.L63= | Silent (SNP) | VAF 79/530 reads (15%) | called by muse, mutect2, varscan2
- ACHE | c.675G>A p.P225= | Silent (SNP) | VAF 84/506 reads (17%) | catalogued as rs139672629; called by muse, mutect2, varscan2
- ACTRT3 | c.726G>A p.G242= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV100377542; called by muse, mutect2, varscan2
- ADA | c.168C>G p.L56= | Silent (SNP) | VAF 61/653 reads (9%) | called by muse, mutect2
- ADAMTS10 | c.1257C>G p.L419= | Silent (SNP) | VAF 66/314 reads (21%) | catalogued as COSV54351996; called by muse, mutect2, varscan2
- ADGRE3 | c.1068G>A p.L356= | Silent (SNP) | VAF 47/427 reads (11%) | called by muse, mutect2, varscan2
- ADGRF5 | c.2850C>T p.G950= | Silent (SNP) | VAF 30/245 reads (12%) | catalogued as rs369402264, COSV51938125; called by muse, mutect2, varscan2
- ANKRD22 | c.204C>T p.L68= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- ANLN | c.807G>A p.L269= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- APOBEC1 | c.517C>T p.L173= | Silent (SNP) | VAF 51/309 reads (17%) | catalogued as COSV99980962; called by muse, mutect2, varscan2
- ARFGEF3 | c.5931G>C p.L1977= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- ARHGAP25 | c.1353G>A p.L451= (on ENST00000409202 / NM_001007231.3; = p.L443= on NM_014882.3) | Silent (SNP) | VAF 57/389 reads (15%) | catalogued as COSV54900524; called by muse, mutect2, varscan2
- ASH1L | c.4872G>A p.R1624= | Silent (SNP) | VAF 47/282 reads (17%) | called by muse, mutect2, varscan2
- ATG2A | c.3765C>T p.I1255= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as rs767502321, COSV65966026; called by muse, mutect2, varscan2
- ATP2C1 | c.669C>G p.V223= | Silent (SNP) | VAF 44/330 reads (13%) | called by muse, mutect2, varscan2
- ATP8B4 | c.861G>A p.L287= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1469279726; called by muse, mutect2
- BBC3 | c.24C>T p.A8= | Silent (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- BCAT2 | c.537G>T p.S179= | Silent (SNP) | VAF 52/352 reads (15%) | called by muse, mutect2, varscan2
- BICD2 | c.2199C>G p.L733= | Silent (SNP) | VAF 52/282 reads (18%) | called by muse, varscan2
- C5AR1 | c.228C>G p.L76= | Silent (SNP) | VAF 88/510 reads (17%) | catalogued as COSV61893075; called by muse, mutect2, varscan2
- C5orf38 | c.108C>G p.L36= | Silent (SNP) | VAF 85/436 reads (19%) | catalogued as COSV57412597; called by muse, mutect2, varscan2
- CAD | c.3372C>T p.V1124= | Silent (SNP) | VAF 27/203 reads (13%) | catalogued as COSV53031818; called by muse, mutect2, varscan2
- CALCA | c.36C>A p.L12= | Silent (SNP) | VAF 100/527 reads (19%) | called by muse, mutect2, varscan2
- CCDC178 | c.96G>A p.K32= | Silent (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- CCDC88A | c.4398G>A p.L1466= (on ENST00000436346 / NM_001365480.1; = p.L1465= on NM_001135597.2) | Silent (SNP) | VAF 37/368 reads (10%) | called by muse, mutect2, varscan2
- CDH10 | c.2061G>A p.R687= | Silent (SNP) | VAF 79/558 reads (14%) | catalogued as rs1027042839, COSV52571026, COSV52573259; called by muse, mutect2, varscan2
- CDH23 | c.6588C>T p.I2196= | Silent (SNP) | VAF 54/236 reads (23%) | called by muse, mutect2
- CDK19 | c.1293G>C p.L431= | Silent (SNP) | VAF 38/302 reads (13%) | called by muse, varscan2
- CEACAM1 | c.831C>T p.F277= | Silent (SNP) | VAF 88/414 reads (21%) | called by muse, mutect2, varscan2
- CHST13 | c.636G>A p.A212= | Silent (SNP) | VAF 48/256 reads (19%) | called by muse, mutect2, varscan2
- CLASP2 | c.2992C>T p.L998= (on ENST00000359576; = p.L997= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 18/165 reads (11%) | called by muse, mutect2, varscan2
- CLCN6 | c.423C>G p.V141= | Silent (SNP) | VAF 22/321 reads (7%) | catalogued as COSV56742633; called by muse, mutect2
- CLSTN3 | c.1722C>T p.S574= | Silent (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- CNPPD1 | c.1191C>T p.V397= | Silent (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- COL13A1 | c.1449G>A p.Q483= (on ENST00000398978 / NM_001130103.2; = p.Q426= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- CRB2 | c.117C>A p.P39= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV63505432; called by muse, mutect2, varscan2
- CSGALNACT2 | c.903G>A p.K301= | Silent (SNP) | VAF 35/160 reads (22%) | called by muse, mutect2, varscan2
- CUTA | c.240C>T p.V80= (on ENST00000488034 / NM_001014840.2; = p.V57= on NM_015921.3) | Silent (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- CWF19L2 | c.1464G>C p.L488= | Silent (SNP) | VAF 38/265 reads (14%) | catalogued as COSV56508281, COSV56521931; called by muse, mutect2, varscan2
- DENND1A | c.699G>T p.P233= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV65326192; called by muse, mutect2, varscan2
- DENND6A | c.174C>T p.F58= | Silent (SNP) | VAF 96/615 reads (16%) | catalogued as rs143936981; called by muse, mutect2, varscan2
- DGKQ | c.2706C>T p.I902= | Silent (SNP) | VAF 34/199 reads (17%) | called by muse, mutect2, varscan2
- DLEC1 | c.4632G>A p.Q1544= | Silent (SNP) | VAF 46/506 reads (9%) | called by muse, mutect2
- DLG5 | c.3030G>T p.L1010= | Silent (SNP) | VAF 47/255 reads (18%) | called by muse, mutect2, varscan2
- DNAJC6 | c.693C>T p.L231= | Silent (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- DSC1 | c.909C>T p.I303= | Silent (SNP) | VAF 40/188 reads (21%) | catalogued as COSV57142098; called by muse, mutect2, varscan2
- EEF1A2 | c.1272C>T p.F424= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as rs1490367198; called by muse, mutect2, varscan2
- EHF | c.498C>T p.F166= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, varscan2
- EIF2B3 | c.504C>G p.L168= | Silent (SNP) | VAF 33/266 reads (12%) | called by muse, mutect2, varscan2
- ELMO1 | c.1389G>A p.L463= | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV100166301; called by muse, mutect2
- EPHB1 | c.672A>T p.T224= | Silent (SNP) | VAF 34/256 reads (13%) | catalogued as rs749238051; called by muse, mutect2, varscan2
- EPPK1 | c.6393G>C p.V2131= | Silent (SNP) | VAF 34/450 reads (8%) | called by muse, mutect2
- FADS3 | c.276G>A p.L92= | Silent (SNP) | VAF 31/209 reads (15%) | catalogued as rs1218329614; called by muse, mutect2, varscan2
- FBXO8 | c.258G>A p.L86= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as COSV67031025; called by muse, mutect2, varscan2
- FERMT3 | c.624C>G p.L208= | Silent (SNP) | VAF 53/330 reads (16%) | called by muse, mutect2, varscan2
- FGL2 | c.255C>G p.L85= | Silent (SNP) | VAF 45/383 reads (12%) | called by muse, mutect2, varscan2
- FLT3 | c.1491G>C p.S497= | Silent (SNP) | VAF 32/247 reads (13%) | called by muse, mutect2, varscan2
- FYCO1 | c.1365C>G p.L455= | Silent (SNP) | VAF 56/498 reads (11%) | called by muse, varscan2
- FYCO1 | c.1296C>T p.V432= | Silent (SNP) | VAF 103/942 reads (11%) | called by muse, varscan2
- FYCO1 | c.873C>A p.L291= | Silent (SNP) | VAF 35/265 reads (13%) | called by muse, mutect2, varscan2
- FYCO1 | c.625C>T p.L209= | Silent (SNP) | VAF 58/502 reads (12%) | catalogued as COSV56115274; called by muse, mutect2, varscan2
- GBP3 | c.708C>T p.F236= | Silent (SNP) | VAF 38/271 reads (14%) | catalogued as rs774535164, COSV52518034; called by muse, mutect2, varscan2
- GCFC2 | c.96G>A p.P32= | Silent (SNP) | VAF 105/661 reads (16%) | catalogued as rs1250591512, COSV58083329; called by muse, mutect2, varscan2
- GJC2 | c.753G>T p.P251= | Silent (SNP) | VAF 177/924 reads (19%) | called by muse, mutect2, varscan2
- GLI1 | c.2154G>A p.L718= | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- GPR108 | c.924C>T p.L308= (on ENST00000264080 / NM_001080452.1; = p.L66= on NM_020171.2) | Silent (SNP) | VAF 51/286 reads (18%) | catalogued as rs1272115760; called by muse, mutect2, varscan2
- H2BC8 | c.222C>T p.I74= | Silent (SNP) | VAF 39/239 reads (16%) | catalogued as rs767133701, COSV55127109; called by muse, mutect2, varscan2
- HDHD3 | c.147C>T p.F49= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs1225610187; called by muse, mutect2, varscan2
- HNRNPU | c.2234G>A p.*745= (on ENST00000283179; = p.*807= on NM_004501.3) | Silent (SNP) | VAF 26/230 reads (11%) | called by muse, mutect2, varscan2
- HOXA2 | c.957C>T p.V319= | Silent (SNP) | VAF 122/679 reads (18%) | called by muse, mutect2, varscan2
- HPR | c.798G>A p.P266= | Silent (SNP) | VAF 56/350 reads (16%) | catalogued as rs771432340, COSV57182510; called by muse, mutect2, varscan2
- HRH2 | c.201C>T p.L67= | Silent (SNP) | VAF 50/251 reads (20%) | catalogued as rs149131528; called by muse, mutect2, varscan2
- HSPH1 | c.1305G>A p.L435= | Silent (SNP) | VAF 42/246 reads (17%) | called by muse, mutect2, varscan2
- IGKV2D-28 | c.294G>C p.L98= | Silent (SNP) | VAF 20/77 reads (26%) | called by mutect2, varscan2
- KCNA2 | c.630C>T p.I210= | Silent (SNP) | VAF 41/205 reads (20%) | catalogued as rs761112803, COSV60371855; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNK6 | c.309G>A p.L103= | Silent (SNP) | VAF 56/467 reads (12%) | catalogued as rs1215193238; called by muse, mutect2, varscan2
- KCNT1 | c.2988C>A p.G996= (on ENST00000488444; = p.G1015= on NM_020822.3) | Silent (SNP) | VAF 37/196 reads (19%) | catalogued as COSV53696202; called by muse, mutect2, varscan2
- KDELR2 | c.333C>T p.H111= | Silent (SNP) | VAF 22/110 reads (20%) | catalogued as rs540799139, COSV51726898; called by muse, mutect2, varscan2
- KDM6B | c.240G>C p.A80= | Silent (SNP) | VAF 46/303 reads (15%) | called by muse, mutect2, varscan2
- KIAA2026 | c.2010G>A p.Q670= | Silent (SNP) | VAF 67/338 reads (20%) | called by muse, mutect2, varscan2
- KIF6 | c.1818G>A p.L606= | Silent (SNP) | VAF 37/233 reads (16%) | catalogued as COSV54677493; called by muse, mutect2, varscan2
- LAMA1 | c.6468C>T p.F2156= | Silent (SNP) | VAF 44/497 reads (9%) | called by muse, mutect2
- LDLR | c.825C>T p.L275= | Silent (SNP) | VAF 46/592 reads (8%) | catalogued as CD982739; called by muse, mutect2
- LRATD2 | c.291C>T p.F97= | Silent (SNP) | VAF 87/459 reads (19%) | catalogued as rs375555909, COSV59230149; called by muse, mutect2, varscan2
- LRBA | c.352C>T p.L118= | Silent (SNP) | VAF 41/234 reads (18%) | catalogued as rs754309081; called by muse, mutect2, varscan2
- LRIG2 | c.1545G>C p.V515= | Silent (SNP) | VAF 15/216 reads (7%) | catalogued as COSV63160749; called by muse, mutect2
- LRWD1 | c.411G>C p.L137= | Silent (SNP) | VAF 22/254 reads (9%) | called by muse, mutect2
- LVRN | c.2217G>A p.V739= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100773361; called by muse, mutect2, varscan2
- LY9 | c.837G>A p.K279= | Silent (SNP) | VAF 40/223 reads (18%) | catalogued as rs1023088489; called by muse, mutect2, varscan2
- MBOAT1 | c.447C>T p.I149= | Silent (SNP) | VAF 30/243 reads (12%) | called by muse, mutect2, varscan2
- METAP1D | c.843C>T p.F281= | Silent (SNP) | VAF 36/249 reads (14%) | called by muse, mutect2, varscan2
- MICAL2 | c.1878G>A p.L626= | Silent (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- MMP15 | c.430C>T p.L144= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV54680657; called by muse, mutect2, varscan2
- MMP24 | c.360C>T p.I120= | Silent (SNP) | VAF 58/301 reads (19%) | called by muse, mutect2, varscan2
- MS4A7 | c.630C>G p.L210= | Silent (SNP) | VAF 27/196 reads (14%) | called by muse, mutect2, varscan2
- MSH6 | c.93C>G p.G31= | Silent (SNP) | VAF 66/457 reads (14%) | called by muse, mutect2, varscan2
- MTHFD1 | c.699C>T p.V233= | Silent (SNP) | VAF 108/700 reads (15%) | catalogued as rs757491631; called by muse, mutect2, varscan2
- MUC17 | c.10326C>A p.I3442= | Silent (SNP) | VAF 34/191 reads (18%) | catalogued as COSV60294959; called by muse, mutect2, varscan2
- MUC17 | c.12576G>A p.V4192= | Silent (SNP) | VAF 36/234 reads (15%) | called by muse, mutect2, varscan2
- MUC5B | c.2232C>A p.G744= | Silent (SNP) | VAF 66/360 reads (18%) | called by muse, mutect2, varscan2
- MYLK | c.3414C>G p.L1138= | Silent (SNP) | VAF 22/204 reads (11%) | called by muse, mutect2, varscan2
- MYPN | c.2838C>A p.I946= | Silent (SNP) | VAF 66/382 reads (17%) | catalogued as rs891298566, COSV62731528; called by muse, mutect2, varscan2
- NCAPH | c.1170C>T p.F390= | Silent (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- NCEH1 | c.84G>A p.P28= | Silent (SNP) | VAF 53/305 reads (17%) | catalogued as rs760453997, COSV56434662; called by muse, mutect2, varscan2
- NCOA4 | c.1647C>T p.L549= | Silent (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2
- NETO1 | c.249C>T p.Y83= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- NFATC1 | c.915C>G p.T305= | Silent (SNP) | VAF 71/429 reads (17%) | called by muse, mutect2, varscan2
- NIPSNAP2 | c.840G>A p.L280= | Silent (SNP) | VAF 39/237 reads (16%) | called by muse, mutect2, varscan2
- NOD1 | c.1839G>A p.L613= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as rs768730451; called by muse, mutect2, varscan2
- NOS3 | c.3507G>C p.V1169= | Silent (SNP) | VAF 54/278 reads (19%) | catalogued as COSV52491595; called by muse, mutect2, varscan2
- OR11G2 | c.717C>G p.V239= | Silent (SNP) | VAF 35/310 reads (11%) | called by muse, mutect2, varscan2
- OR1S2 | c.903C>T p.F301= | Silent (SNP) | VAF 30/169 reads (18%) | called by muse, mutect2, varscan2
- OR2T11 | c.99G>A p.L33= | Silent (SNP) | VAF 59/369 reads (16%) | called by muse, mutect2, varscan2
- OR2T34 | c.687C>G p.L229= | Silent (SNP) | VAF 44/354 reads (12%) | catalogued as COSV60899462; called by muse, mutect2, varscan2
- OR2Y1 | c.420C>G p.L140= | Silent (SNP) | VAF 41/227 reads (18%) | catalogued as COSV57138187; called by muse, mutect2, varscan2
- OR51E1 | c.664C>T p.L222= | Silent (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- OR52D1 | c.18C>T p.L6= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- OR8G5 | c.678C>G p.L226= | Silent (SNP) | VAF 59/302 reads (20%) | called by muse, mutect2, varscan2
- P2RX4 | c.1011C>T p.I337= | Silent (SNP) | VAF 46/370 reads (12%) | called by muse, mutect2, varscan2
- PACRG | c.327G>T p.L109= | Silent (SNP) | VAF 29/163 reads (18%) | called by muse, mutect2, varscan2
- PAPPA | c.2082C>T p.F694= | Silent (SNP) | VAF 13/158 reads (8%) | catalogued as rs868095066, COSV60286937; called by muse, mutect2
- PBXIP1 | c.945G>T p.G315= | Silent (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- PCDH11X | c.1578G>A p.K526= | Silent (SNP) | VAF 39/331 reads (12%) | catalogued as COSV100007548; called by muse, mutect2, varscan2
- PCDH18 | c.3213G>A p.P1071= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs774181850, COSV100787345; called by muse, mutect2, varscan2
- PCDH7 | c.396C>T p.I132= | Silent (SNP) | VAF 45/199 reads (23%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1866C>T p.F622= | Silent (SNP) | VAF 108/523 reads (21%) | called by muse, mutect2, varscan2
- PCDHB1 | c.831A>T p.I277= | Silent (SNP) | VAF 92/388 reads (24%) | called by muse, mutect2, varscan2
- PDE1C | c.1494C>T p.V498= | Silent (SNP) | VAF 18/148 reads (12%) | catalogued as COSV58505698; called by muse, mutect2, varscan2
- PDS5B | c.1506C>G p.L502= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- PEG3 | c.657G>A p.E219= | Silent (SNP) | VAF 48/221 reads (22%) | catalogued as rs745666478; called by muse, mutect2, varscan2
- PINK1 | c.1557G>C p.L519= | Silent (SNP) | VAF 75/478 reads (16%) | catalogued as CD061456; called by muse, mutect2, varscan2
- PKHD1L1 | c.4929T>C p.A1643= | Silent (SNP) | VAF 28/298 reads (9%) | called by muse, mutect2
- PKMYT1 | c.510C>T p.C170= | Silent (SNP) | VAF 53/376 reads (14%) | catalogued as rs1321208229, COSV51890778; called by muse, mutect2, varscan2
- PLB1 | c.3096G>A p.L1032= | Silent (SNP) | VAF 36/297 reads (12%) | called by muse, mutect2, varscan2
- PLCB3 | c.2958C>G p.V986= | Silent (SNP) | VAF 46/292 reads (16%) | catalogued as COSV54189713; called by muse, mutect2, varscan2
- PLCXD2 | c.24G>A p.R8= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV101210147, COSV67341524; called by muse, mutect2
- PLPPR4 | c.1911G>A p.P637= | Silent (SNP) | VAF 43/261 reads (16%) | catalogued as rs201385642, COSV100926892, COSV64567674; called by muse, mutect2, varscan2
- PLTP | c.57C>T p.F19= | Silent (SNP) | VAF 133/694 reads (19%) | catalogued as rs1165365732, COSV100819086; called by muse, mutect2, varscan2
- POMGNT1 | c.195C>A p.I65= | Silent (SNP) | VAF 121/694 reads (17%) | called by muse, mutect2, varscan2
- PRC1 | c.183G>C p.L61= | Silent (SNP) | VAF 21/188 reads (11%) | called by muse, mutect2, varscan2
- RAB6C | c.444G>C p.L148= | Silent (SNP) | VAF 20/522 reads (4%) | catalogued as COSV69339264; called by muse, mutect2
- RASSF5 | c.24C>T p.I8= | Silent (SNP) | VAF 58/347 reads (17%) | catalogued as rs1553393909; called by muse, mutect2, varscan2
- RNF122 | c.192G>A p.R64= | Silent (SNP) | VAF 66/570 reads (12%) | catalogued as rs767120987; called by muse, mutect2, varscan2
- RNF128 | c.789G>A p.L263= (on ENST00000255499 / NM_194463.2; = p.L237= on NM_024539.3) | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV55256023; called by muse, mutect2, varscan2
- SCN11A | c.3384C>T p.I1128= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as rs1237257261, COSV100182201; called by muse, mutect2
- SCN2A | c.5868G>A p.E1956= | Silent (SNP) | VAF 45/485 reads (9%) | catalogued as COSV51835726, COSV51837444; called by muse, mutect2
- SCN3A | c.4836G>A p.K1612= | Silent (SNP) | VAF 124/469 reads (26%) | called by muse, mutect2, varscan2
- SERPIND1 | c.483G>A p.A161= | Silent (SNP) | VAF 68/441 reads (15%) | catalogued as rs200862324; called by muse, mutect2, varscan2
- SHB | c.1529G>A p.*510= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV66628562; called by muse, mutect2
- SLC18A2 | c.75C>T p.I25= | Silent (SNP) | VAF 174/495 reads (35%) | catalogued as rs766986252; called by muse, mutect2, varscan2
- SLC22A5 | c.1195C>A p.R399= | Silent (SNP) | VAF 101/503 reads (20%) | catalogued as CM100210, COSV55372551; called by muse, mutect2, varscan2
- SLC25A41 | c.1044G>A p.L348= | Silent (SNP) | VAF 32/213 reads (15%) | catalogued as rs1224724120, COSV58599589; called by muse, mutect2, varscan2
- SLC27A2 | c.426C>T p.S142= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs1160558432; called by muse, mutect2, varscan2
- SLC47A1 | c.1269C>T p.I423= | Silent (SNP) | VAF 48/318 reads (15%) | catalogued as rs774900748, COSV99565586; called by muse, mutect2, varscan2
- SLCO2B1 | c.558G>T p.L186= | Silent (SNP) | VAF 28/216 reads (13%) | called by muse, mutect2, varscan2
- SLITRK2 | c.270T>A p.T90= | Silent (SNP) | VAF 92/208 reads (44%) | called by muse, mutect2, varscan2
- SPATC1L | c.621C>T p.I207= (on ENST00000291672 / NM_001142854.2; = p.I53= on NM_032261.5) | Silent (SNP) | VAF 78/449 reads (17%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.663G>A p.L221= | Silent (SNP) | VAF 43/274 reads (16%) | called by muse, mutect2, varscan2
- STARD13 | c.2769G>A p.E923= (on ENST00000336934 / NM_001243476.3; = p.E805= on NM_052851.3) | Silent (SNP) | VAF 59/459 reads (13%) | catalogued as COSV55237568; called by muse, mutect2, varscan2
- STAT2 | c.691C>T p.L231= | Silent (SNP) | VAF 62/377 reads (16%) | called by muse, mutect2, varscan2
- STK11 | c.1200G>A p.L400= | Silent (SNP) | VAF 67/431 reads (16%) | catalogued as rs368661707; ClinVar: likely benign; called by muse, mutect2, varscan2
- STT3A | c.30C>G p.S10= | Silent (SNP) | VAF 29/196 reads (15%) | called by muse, mutect2, varscan2
- SYNE1 | c.25413C>T p.L8471= (on ENST00000367255 / NM_182961.4; = p.L8423= on NM_033071.3) | Silent (SNP) | VAF 80/477 reads (17%) | called by muse, mutect2, varscan2
- TAGAP | c.1620G>A p.P540= | Silent (SNP) | VAF 26/170 reads (15%) | catalogued as rs200549687, COSV57852138; called by muse, mutect2, varscan2
- TAS2R7 | c.693G>A p.V231= | Silent (SNP) | VAF 35/273 reads (13%) | catalogued as COSV53689132; called by muse, mutect2, varscan2
- TAS2R8 | c.456G>A p.L152= | Silent (SNP) | VAF 50/249 reads (20%) | called by muse, mutect2, varscan2
- TBC1D10B | c.816C>A p.S272= | Silent (SNP) | VAF 30/434 reads (7%) | called by muse, mutect2
167 further variants in this file (0 protein-altering or splice-affecting, 32 silent, 135 other) are not listed here.
